Somatic mutation profile of tumor specimen TCGA-FD-A5C0-01A (aliquot TCGA-FD-A5C0-01A-11D-A289-08) from TCGA case TCGA-FD-A5C0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.6 years (22,500 days).
Specimen TCGA-FD-A5C0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53859d97-d2c2-4467-873c-1ce481722f19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A5C0-10A (Blood Derived Normal), aliquot TCGA-FD-A5C0-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f22b1c97-be79-4e43-9054-11afd15e04d1

The open-access MAF lists 143 somatic variants for this specimen: 105 protein-altering or splice-affecting, 31 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 31, Frame Shift Del 7, Nonsense Mutation 5, RNA 4, Splice Site 4, Splice Region 3, 3'UTR 1, 5'Flank 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs1131690884, CM030505, COSV99923959; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACADS | c.1061A>G p.E354G | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54370538; called by muse, mutect2, varscan2
- AGRN | c.3674G>A p.R1225Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1486462433, COSV65072740; called by muse, mutect2, varscan2
- ARAP1 | c.748-7G>A | Splice Region (SNP) | VAF 157/267 reads (59%) | catalogued as COSV61995765; called by muse, mutect2, varscan2
- ASXL2 | c.187A>G p.N63D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55469291; called by muse, mutect2, varscan2
- CABP4 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV57800416; called by muse, mutect2, varscan2
- CALY | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99428607; called by muse, mutect2, varscan2
- CASP5 | c.1211del p.Q404Rfs*16 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as COSV52832465; called by mutect2, pindel, varscan2
- CBFA2T3 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV51933887; called by muse, mutect2, varscan2
- CBWD1 | c.1069T>A p.L357M | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV58703634; called by muse, mutect2, varscan2
- CCDC151 | c.952A>G p.M318V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.155); catalogued as rs768744014, COSV62699401; called by muse, mutect2, varscan2
- CCDC27 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53904236; called by muse, mutect2, varscan2
- CDH16 | c.2327del p.R776Pfs*2 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as COSV100233701, COSV55340243; called by mutect2, pindel, varscan2
- CEACAM7 | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV50075485; called by muse, mutect2, varscan2
- CFLAR | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV58582444; called by muse, mutect2, varscan2
- CIT | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55885853, COSV99948716; called by muse, mutect2, varscan2
- COBL | c.281T>A p.L94H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV54360842, COSV99473924; called by muse, mutect2, varscan2
- COL25A1 | c.1710+2T>C p.X570_splice | Splice Site (SNP) | VAF 13/79 reads (16%) | catalogued as COSV67660483; called by muse, mutect2, varscan2
- CWF19L1 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62498936, COSV62499853; called by muse, mutect2, varscan2
- DHX38 | c.2794G>A p.A932T | Missense Mutation (SNP) | VAF 192/256 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415450076, COSV51701407; called by muse, mutect2, varscan2
- DNAH5 | c.8276T>C p.V2759A | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV54257189, COSV99444573; called by muse, mutect2, varscan2
- DOCK10 | c.4097C>A p.S1366Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV51430560; called by muse, mutect2, varscan2
- DOT1L | c.163A>G p.M55V | Missense Mutation (SNP) | VAF 130/547 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV67109017; called by muse, mutect2, varscan2
- DSG3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57126399; called by muse, mutect2, varscan2
- EGLN2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs541800008, COSV100393716, COSV58281438; called by muse, mutect2, varscan2
- ELMOD2 | c.534-1G>A p.X178_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV60271650; called by muse, mutect2, varscan2
- ENPP1 | c.1802C>T p.T601M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as rs763005831, COSV62935311; called by muse, mutect2, varscan2
- EP300 | c.3740G>T p.C1247F | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54347166; called by muse, mutect2, varscan2
- ESRP2 | c.1920_1921del p.Y640* (on ENST00000565858 / NM_001365264.1; = p.Y630* on NM_024939.3 and 1 other RefSeq transcript) | Nonsense Mutation (DEL) | VAF 353/593 reads (60%) | catalogued as COSV52176716; called by mutect2, pindel, varscan2
- FAM135B | c.1378C>A p.L460I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52733210, COSV52757897; called by muse, mutect2, varscan2
- FAM90A1 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.993); catalogued as COSV56715331; called by muse, mutect2, varscan2
- FGA | c.2269T>C p.S757P | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1359411826, COSV57402064; called by muse, mutect2, varscan2
- GLCCI1 | c.1163A>G p.Y388C | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.951); catalogued as rs757877476, COSV56202243; called by muse, mutect2, varscan2
- IL17RD | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs199540136, COSV56343740; called by muse, mutect2, varscan2
- KCNJ16 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV52257893; called by muse, mutect2, varscan2
- KCTD19 | c.1651G>C p.A551P | Missense Mutation (SNP) | VAF 601/806 reads (75%) | SIFT tolerated (0.26); PolyPhen benign (0.143); catalogued as COSV58575736; called by muse, mutect2, varscan2
- KDM6A | c.1329+1G>A p.X443_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV65047198; called by muse, mutect2, varscan2
- KIAA1586 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs1466196529, COSV66057552; called by muse, mutect2, varscan2
- KIF26B | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as rs149649213; called by muse, mutect2, varscan2
- LPIN2 | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55245233; called by muse, mutect2, varscan2
- LRIT1 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs750726561, COSV64513756; called by muse, mutect2, varscan2
- LRP2 | c.5813C>G p.T1938S | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as COSV55574577, COSV55578442; called by muse, mutect2, varscan2
- LRP6 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV53785999, COSV99742839; called by muse, mutect2, varscan2
- LSG1 | c.1658G>A p.R553K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54573110; called by muse, mutect2, varscan2
- MAP11 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1175654618, COSV57588536; called by muse, mutect2, varscan2
- MORC1 | c.1787A>T p.K596I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV51733218; called by muse, mutect2, varscan2
- MUSK | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 54/226 reads (24%) | catalogued as COSV99503891; called by muse, mutect2, varscan2
- NEB | c.13564C>A p.L4522M | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV51466351; called by muse, mutect2, varscan2
- NLGN1 | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV64336412; called by muse, mutect2, varscan2
- NLRP2 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.284); catalogued as rs766338756, COSV54761413; called by muse, mutect2, varscan2
- NOTCH3 | c.4703G>A p.R1568Q | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs777488182, COSV54653543, COSV99659464; called by muse, mutect2, varscan2
- NOX3 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV50153449, COSV50166535; called by muse, mutect2, varscan2
- OBSCN | c.21163C>T p.P7055S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs201574059; called by muse, mutect2, varscan2
- OCA2 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs140556122; called by muse, mutect2, varscan2
- OLIG2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1375013666, COSV60972780; called by muse, mutect2, varscan2
- OR10R2 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs149832721; called by muse, mutect2, varscan2
- OR2T4 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV100822426, COSV63545270; called by muse, mutect2, varscan2
- PACSIN3 | c.661A>G p.M221V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV54068165; called by muse, mutect2, varscan2
- PAX4 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58391733; called by muse, mutect2, varscan2
- PCDH15 | c.4564C>T p.P1522S | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated, low confidence (0.55); PolyPhen probably damaging (0.987); catalogued as rs373365619; called by muse, mutect2, varscan2
- PCDHB7 | c.1496C>A p.P499H | Missense Mutation (SNP) | VAF 122/221 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV50828236; called by muse, mutect2, varscan2
- PCED1A | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1472922878, COSV62314156; called by muse, mutect2, varscan2
- PDZD2 | c.2474A>G p.E825G | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV56875377; called by muse, mutect2, varscan2
- PDZD8 | c.3424A>C p.S1142R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); catalogued as COSV53691582, COSV53694060; called by muse, mutect2, varscan2
- PGBD2 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61401379; called by muse, mutect2, varscan2
- PIK3CA | c.2013A>G p.L671= | Splice Region (SNP) | VAF 34/104 reads (33%) | catalogued as rs1060503813, COSV99835709; ClinVar: likely benign; called by muse, mutect2, varscan2
- PNMA2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs750103015, COSV72908560; called by muse, mutect2, varscan2
- PNPLA5 | c.693del p.S232Afs*4 | Frame Shift Del (DEL) | VAF 23/157 reads (15%) | catalogued as rs1218927828; called by mutect2, pindel, varscan2
- PRAMEF19 | c.387G>C p.M129I | Missense Mutation (SNP) | VAF 50/1167 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs1290709364; called by muse, mutect2
- PTPN11 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV61014114; called by muse, mutect2, varscan2
- RBM25 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV56203432; called by muse, mutect2, varscan2
- RIOK2 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746579668, COSV51615446, COSV99299923; called by muse, mutect2, varscan2
- SCN11A | c.5035C>A p.R1679S | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56566354, COSV56579756; called by muse, mutect2, varscan2
- SETD2 | c.4628G>A p.R1543Q | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs752011468, COSV57446817; called by muse, mutect2, varscan2
- SI | c.3152C>T p.P1051L | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52304775, COSV52306563; called by muse, mutect2, varscan2
- SLC10A2 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV55362158; called by muse, mutect2, varscan2
- SLC25A38 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56195690; called by muse, mutect2, varscan2
- SLC39A1 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 34/321 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV57841976, COSV57843077; called by muse, mutect2
- SMG5 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs765958889, COSV62438289; called by muse, mutect2, varscan2
- SPACA3 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs761168205, COSV52192887; called by muse, mutect2, varscan2
- THAP11 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 94/1018 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54647728; called by muse, mutect2
- TIPARP | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV55815933; called by muse, mutect2, varscan2
- TNRC6A | c.2839A>G p.N947D | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV59370998; called by muse, mutect2, varscan2
- TNXB | c.11592C>A p.S3864R (on ENST00000647633; = p.S3617R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV64490471; called by muse, mutect2, varscan2
- TRIML1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV60197274; called by muse, mutect2, varscan2
- TTLL4 | c.3521G>T p.C1174F | Missense Mutation (SNP) | VAF 116/190 reads (61%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV51439989; called by muse, mutect2, varscan2
- VCAN | c.4007G>A p.R1336Q | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs372244245, COSV54098984; called by muse, mutect2, varscan2
- VPS50 | c.2101G>C p.E701Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.202); catalogued as COSV59923735; called by muse, mutect2, varscan2
- WRNIP1 | c.1939C>G p.Q647E | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs770584399, COSV66356497; called by muse, mutect2, varscan2
- ZBTB39 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as COSV55631194; called by muse, mutect2, varscan2
- ZFPM2 | c.1245G>C p.L415F | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as COSV65876454; called by muse, mutect2, varscan2
- ZIM3 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV99517901; called by muse, mutect2, varscan2
- ZIM3 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV54140803; called by muse, mutect2, varscan2
- ZNF140 | c.1052A>G p.H351R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60580158; called by muse, mutect2, varscan2
- ZNF257 | c.1264A>G p.K422E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV71312482; called by muse, mutect2, varscan2
- ZNF518A | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100283422; called by muse, mutect2, varscan2
- CABIN1 | c.3798_3805dup p.A1269Gfs*7 | Frame Shift Ins (INS) | VAF 41/189 reads (22%) | called by mutect2, varscan2
- COL7A1 | c.8789del p.P2930Hfs*22 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- FAT4 | c.10455del p.D3486Ifs*14 | Frame Shift Del (DEL) | VAF 25/198 reads (13%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 93/375 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH7B | c.1639_1651del p.R547Tfs*96 | Frame Shift Del (DEL) | VAF 19/93 reads (20%) | called by mutect2, pindel, varscan2
- NBPF25P | n.1021del | Splice Region (DEL) | VAF 170/363 reads (47%) | called by mutect2, varscan2
- PRAMEF18 | c.387G>C p.M129I | Missense Mutation (SNP) | VAF 28/351 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.103); called by muse, mutect2
- STON1-GTF2A1L | c.3436_3441+7del p.X1146_splice | Splice Site (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- TTLL4 | c.843del p.S282Vfs*29 | Frame Shift Del (DEL) | VAF 81/186 reads (44%) | called by mutect2, pindel, varscan2
- AKAP7 | c.318G>A p.Q106= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV63505916; called by muse, mutect2, varscan2
- ARSA | c.1044C>A p.A348= | Silent (SNP) | VAF 2/16 reads (13%) | catalogued as COSV99332332; called by muse, mutect2
- C1QL4 | c.318C>T p.Y106= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs778236378, COSV57746317; called by muse, mutect2, varscan2
- CPVL | c.936T>C p.S312= | Silent (SNP) | VAF 49/100 reads (49%) | catalogued as COSV55309638; called by muse, mutect2, varscan2
- EYA2 | c.132G>A p.L44= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV57951624; called by muse, mutect2, varscan2
- FBXL8 | c.882C>T p.F294= | Silent (SNP) | VAF 70/86 reads (81%) | catalogued as rs1394715713, COSV50460371; called by muse, mutect2, varscan2
- FGFRL1 | c.930C>T p.D310= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as rs142743042; called by muse, mutect2, varscan2
- FPR2 | c.516G>A p.G172= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as rs764688069, COSV60674734; called by muse, mutect2, varscan2
- HCN1 | c.2163C>T p.S721= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs1232289132, COSV57541277; called by muse, mutect2, varscan2
- KCNK15 | c.309G>A p.T103= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs776412652, COSV65720948; called by muse, mutect2, varscan2
- KLC2 | c.390C>T p.L130= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs754740944, COSV57584669; called by muse, mutect2, varscan2
- KRT84 | c.642C>T p.F214= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs1003195648, COSV57770809; called by muse, mutect2, varscan2
- LTN1 | c.1744T>C p.L582= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1468123185, COSV63735537; called by muse, mutect2, varscan2
- LYG1 | c.39G>A p.L13= | Silent (SNP) | VAF 39/151 reads (26%) | catalogued as COSV57916451; called by muse, mutect2, varscan2
- MAGEB6 | c.1155T>A p.G385= | Silent (SNP) | VAF 92/135 reads (68%) | catalogued as COSV66873317; called by muse, mutect2, varscan2
- MYO18A | c.2556T>C p.D852= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV62874767; called by muse, mutect2, varscan2
- NUP98 | c.4110A>T p.S1370= (on ENST00000359171 / NM_001365126.1; = p.S1353= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 85/140 reads (61%) | catalogued as COSV61439768; called by muse, mutect2, varscan2
- OR52N5 | c.429C>T p.T143= | Silent (SNP) | VAF 44/57 reads (77%) | catalogued as COSV57699634; called by muse, mutect2, varscan2
- PLCH1 | c.4332T>C p.H1444= (on ENST00000340059 / NM_001130960.2; = p.H1436= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV58211597; called by muse, mutect2, varscan2
- RAVER1 | c.1245C>T p.L415= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs760743081, COSV53349248; called by mutect2, varscan2
- RRP9 | c.1218G>A p.G406= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV51757210; called by muse, mutect2, varscan2
- TKTL2 | c.1572C>T p.D524= | Silent (SNP) | VAF 43/244 reads (18%) | catalogued as rs1441583883, COSV54921721; called by muse, mutect2, varscan2
- TMC4 | c.1467C>G p.L489= (on ENST00000617472 / NM_001145303.3; = p.L483= on NM_144686.4) | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV55829161; called by muse, mutect2, varscan2
- TMEM260 | c.1122A>G p.A374= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV55103405; called by muse, mutect2, varscan2
- TPCN1 | c.381C>T p.A127= | Silent (SNP) | VAF 118/559 reads (21%) | catalogued as COSV59241571; called by muse, mutect2, varscan2
- TPGS2 | c.687C>G p.T229= | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as COSV57541875; called by muse, mutect2, varscan2
- TSEN2 | c.735C>T p.L245= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV53191391; called by muse, mutect2, varscan2
- UBQLN4 | c.471C>T p.S157= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV64145940; called by muse, mutect2
- WDFY3 | c.4314C>G p.V1438= | Silent (SNP) | VAF 35/235 reads (15%) | catalogued as COSV55705071; called by muse, mutect2, varscan2
- ZFYVE19 | c.60A>G p.R20= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV54542458; called by muse, mutect2, varscan2
- ZNF831 | c.687G>A p.R229= | Silent (SNP) | VAF 67/145 reads (46%) | catalogued as COSV100926051, COSV64046073; called by muse, mutect2, varscan2
- C3P1 | n.2738G>A | RNA (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- DCHS2 | n.1349G>A | RNA (SNP) | VAF 38/192 reads (20%) | catalogued as rs777767833, COSV59741435; called by muse, mutect2, varscan2
- DLEC1 | c.*74C>T | 3'UTR (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100085964; called by muse, mutect2, varscan2
- FAM74A3 | n.72G>A | RNA (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- MICD | chr6:29975322 G>A | 5'Flank (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- NBPF7 | n.105G>A | RNA (SNP) | VAF 28/410 reads (7%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-44054G>A | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV67451358; called by muse, mutect2, varscan2
